Somatic mutation profile of tumor specimen C3L-00032-01 (aliquot CPT0001420005) from CPTAC case C3L-00032, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 50.9 years (18,578 days).
Specimen C3L-00032-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 756e71fe-4067-4888-83b4-8dd996cf2297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00032-31 (Blood Derived Normal), aliquot CPT0000110163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f176855d-b577-4db4-a2f5-6c7122f8d64a

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Nonsense Mutation 4, Intron 3, Splice Site 2, Frame Shift Del 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 50/253 reads (20%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 95/442 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 41/191 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 109/573 reads (19%) | hotspot (GDC flag); catalogued as CM110162, COSV64297407, COSV64303225; called by muse, mutect2, varscan2
- AIFM2 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs144648137; called by muse, mutect2, varscan2
- CACNA1H | c.6487G>A p.G2163R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.093); catalogued as rs370724421, COSV99326326; called by muse, mutect2, varscan2
- COL11A2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 149/782 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs553025178, COSV59496583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX1 | c.3845A>G p.N1282S | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs543767455; called by muse, mutect2, varscan2
- CYBA | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs778671805; called by muse, mutect2, varscan2
- DISP1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 113/602 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs146408462; called by muse, mutect2, varscan2
- FAT3 | c.7882G>A p.D2628N | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323881539, COSV99965225; called by muse, mutect2, varscan2
- GIT1 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.511); catalogued as rs745617920; called by muse, mutect2, varscan2
- H1-5 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 109/603 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs557604077; called by muse, mutect2, varscan2
- HRNR | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs764523263; called by muse, mutect2, varscan2
- LRRK1 | c.4664G>T p.G1555V | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99441984; called by muse, mutect2, varscan2
- MPL | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 62/329 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs369486165; called by muse, mutect2, varscan2
- NHS | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 48/232 reads (21%) | catalogued as COSV66283429; called by muse, mutect2, varscan2
- OR7G2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 82/445 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201831795, COSV59687968; called by muse, mutect2, varscan2
- PCDHA2 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 92/436 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs782549832, COSV65370823; called by muse, mutect2, varscan2
- PTPRT | c.2847+1G>A p.X949_splice | Splice Site (SNP) | VAF 16/78 reads (21%) | catalogued as rs763353429, COSV62030660; called by muse, mutect2, varscan2
- SYT7 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776184201; called by muse, mutect2, varscan2
- WDR19 | c.2194G>T p.D732Y | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV56464008; called by muse, mutect2, varscan2
- WWP2 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776834403, COSV100598828; called by muse, mutect2, varscan2
- ASAH2 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CREB3L2 | c.915+1G>A p.X305_splice | Splice Site (SNP) | VAF 76/408 reads (19%) | called by muse, mutect2, varscan2
- CTCF | c.370_371del p.V124Tfs*15 | Frame Shift Del (DEL) | VAF 57/306 reads (19%) | called by mutect2, pindel, varscan2
- ENTPD4 | c.1210A>T p.N404Y | Missense Mutation (SNP) | VAF 84/409 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KLF6 | c.339_350del p.D114_E117del | In Frame Del (DEL) | VAF 107/683 reads (16%) | called by mutect2, pindel
- NUDCD1 | c.1593C>G p.Y531* | Nonsense Mutation (SNP) | VAF 67/363 reads (18%) | called by muse, mutect2, varscan2
- PNMA8B | c.1114del p.L372Sfs*17 | Frame Shift Del (DEL) | VAF 54/226 reads (24%) | called by mutect2, pindel, varscan2
- RXFP4 | c.650T>C p.L217S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SOX17 | c.224dup p.M76Hfs*5 | Frame Shift Ins (INS) | VAF 74/385 reads (19%) | called by mutect2, pindel, varscan2
- ZNF280B | c.1613_1616delinsAAAA p.I538_S539delinsKK | Missense Mutation (ONP) | VAF 6/73 reads (8%) | called by mutect2*, pindel
- CDC42BPG | c.3438C>T p.V1146= | Silent (SNP) | VAF 95/444 reads (21%) | catalogued as rs781628242; called by muse, mutect2, varscan2
- DNAH10 | c.8571C>T p.R2857= (on ENST00000409039; = p.R2796= on NM_207437.3) | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs984555280, COSV68991099; called by muse, varscan2
- HECTD4 | c.8772C>T p.L2924= | Silent (SNP) | VAF 104/432 reads (24%) | catalogued as rs1010465679; called by muse, mutect2, varscan2
- KLF14 | c.948G>A p.A316= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- OR4K1 | c.456C>T p.G152= | Silent (SNP) | VAF 64/361 reads (18%) | catalogued as rs762768302, COSV53459799; called by muse, mutect2, varscan2
- OTOG | c.2544C>T p.F848= | Silent (SNP) | VAF 71/382 reads (19%) | called by muse, mutect2, varscan2
- PPIAL4A | c.39C>T p.D13= | Silent (SNP) | VAF 128/704 reads (18%) | catalogued as rs1239374153; called by muse, mutect2, varscan2
- RYR1 | c.5346C>T p.F1782= | Silent (SNP) | VAF 82/368 reads (22%) | catalogued as rs762772302, COSV62090179; called by muse, mutect2, varscan2
- SHROOM2 | c.1710G>A p.T570= | Silent (SNP) | VAF 51/245 reads (21%) | catalogued as rs553859995; called by muse, mutect2, varscan2
- VPS16 | c.1836G>A p.E612= | Silent (SNP) | VAF 75/314 reads (24%) | called by muse, mutect2, varscan2
- ZIC4 | c.537G>A p.P179= | Silent (SNP) | VAF 26/787 reads (3%) | catalogued as rs1333559436; called by muse, mutect2
- LBHD1 | c.617-143dup | Intron (INS) | VAF 19/100 reads (19%) | called by mutect2, pindel, varscan2
- NDUFA11 | chr19:5893018 C>T | 3'Flank (SNP) | VAF 20/102 reads (20%) | catalogued as rs112416531; called by muse, mutect2
- PDHA1 | c.57+1664G>A | Intron (SNP) | VAF 18/123 reads (15%) | catalogued as rs201567280, COSV63327767, COSV63327819; called by muse, mutect2, varscan2
- RMDN2 | c.453-21865T>G | Intron (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158990 G>A | 5'Flank (SNP) | VAF 35/174 reads (20%) | catalogued as rs967176589; called by muse, mutect2, varscan2
- TMCO1 | c.*23A>G | 3'UTR (SNP) | VAF 82/514 reads (16%) | catalogued as rs765006399; called by muse, mutect2, varscan2
